Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9O5, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9O5-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Left pelvic lymph node, biopsy: Metastatic carcinoma in one lymph node (1/1); see comment.
- B. Right pelvic lymph node, biopsy: Metastatic carcinoma in one lymph node (1/1); see comment.
- C. Left pelvic lymph nodes, dissection: No tumor identified in ten lymph nodes (0/10).
- D. Right pelvic lymph nodes, dissection: Metastatic carcinoma in four of eight lymph nodes (4/8); see comment.
- E. Bladder neck, biopsy: Micro-focus of carcinoma involving muscular tissue.
- F. Prostate, prostatectomy:
1. Prostatic adenocarcinoma, Gleason score 5+4, with extracapsular extension, and focally present at right bladder margin.
2. Seminal vesicle with no tumor.
- G. Left urethral margin, biopsy: Benign fibromuscular tissue, no tumor identified.
- H. Right urethral margin apex, biopsy: Benign fibromuscular tissue, no tumor identified.

COMMENT:

Synoptic Comment for Prostate Tumors

1. Type of tumor: Small acinar adenocarcinoma.
2. Location of tumor: Right and left apex, slides F1, F2; right anterior quadrant, slides F3-F5; right

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
7/23/27/14

[page 2 of 3]
- posterior quadrant, slides F6-F9; left posterior quadrant, slides F10-F13; left anterior quadrant, slide F15; right and left bladder margins, slides F17-F18.
3. Estimated volume of tumor: Approximately 90% of prostate is involved by tumor. The prostate volume is 113 cubic cm; 90% of this is the estimated volume of tumor, which is 102 cubic cm.
4. Gleason score: Primary pattern 5, secondary pattern 4.
5. Estimated volume > Gleason pattern 3: 85%.
6. Involvement of capsule: Tumor invades capsule.
7. Extraprostatic extension: Present, extensive.
8. Status of excision margins for tumor: Tumor extends to inked excision margin at the right bladder margin, slide F17.
Status of excision margins for benign prostate glands: No benign glands present at inked excision margin.
9. Involvement of seminal vesicle: Not present.
10. Perineural infiltration: Present.
11. Prostatic intraepithelial neoplasia (PIN): Present.
12. AJCC/UICC stage: at least T3aN1MX; however, specimen E, which was submitted as "bladder neck," contains a micro-focus of carcinoma. Histologically, this micro-focus of carcinoma involves muscular tissue. No urothelial mucosa is present in the specimen. By morphology, we cannot determine whether the carcinoma is involving the stroma of bladder neck or the stroma of the prostate. Clinical correlation is suggested.
-

Specimen(s) Received

A: Left pelvic lymph node (FS)
B: Right pelvic lymph node (FS)
C: Left pelvic lymph nodes
D: Right pelvic lymph nodes
E: Bladder neck
F: Prostate (fresh)
G: Left urethral margin
H: Right urethral margin/apex

Intraoperative Diagnosis

FS1 (A) Left pelvic lymph node, biopsy: Metastatic prostate carcinoma. [REDACTED]

FS2 (B) Right pelvic lymph node, biopsy: Metastatic prostate carcinoma. [REDACTED]

Clinical History

The patient is a [REDACTED] with prostate carcinoma.

Gross Description

The specimen is received fresh in eight parts, each labeled with the patient's name and medical record number.

Part A is additionally labeled "1. Left pelvic lymph node." It consists of a single firm, oval, pink-tan candidate lymph node, measuring 2.3 x 1.4 x 0.7 cm. The specimen is bisected, and one-half is submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1. From the remaining unused portion, a piece is submitted for the [REDACTED] The remainder of the tissue is submitted in cassette A2.

Part B is additionally labeled "right pelvic lymph node." It consists of a single firm, oval, pink-tan candidate lymph node, measuring 2.3 x 1.5 x 0.7 cm. The specimen is bisected, and one-half of the specimen is submitted for frozen section diagnosis as FS2, with the frozen section remnant submitted in cassette B1. From the remaining unused portion, a piece is saved for the [REDACTED] The remaining tissue is submitted in cassette B2.

Part C is additionally labeled "left pelvic lymph node." It consists of multiple fragments of tan-yellow soft tissue measuring 4.2 x 2.8 x 1.0 cm in aggregate. The specimen is serially sectioned and searched for lymph nodes. Representative sections are submitted as follows:

[page 3 of 3]
Cassette C1: Multiple candidate lymph nodes.
Cassette C2: Two candidate lymph nodes.

Part D is additionally labeled "right pelvic lymph node." It consists of a single fragment of tan-yellow soft tissue measuring 3.5 x 2.2 x 1.0 cm in aggregate. The specimen is serially sectioned and representative sections are submitted as follows:

Cassette D1: Multiple candidate lymph nodes.
Cassette D2: Two candidate lymph nodes.

Part E is additionally labeled "bladder neck." It consists of a single fragment of tan-yellow, soft tissue measuring 1.1 x 0.5 x 0.3 cm. The specimen is entirely submitted in cassette E1.

Part F is additionally labeled "prostate." It consists of a prostate and attached seminal vesicle glands which weigh 66 grams and measure 4.5 cm apex to base, 5.6 cm medial to lateral and 4.5 cm anterior to posterior. The exterior gland is smooth, with multiple surgical clips. The seminal vesicles are soft and tan-red. The left measures 3.2 x 1.8 x 0.5 cm and the right measures 3.2 x 1.6 x 0.4 cm. There are no discrete palpable lesions noted on the surface of the gland. The right is inked green. The left is inked blue and the posterior is inked black. The apical margin and bladder margins are removed. The specimen is serially sectioned into eight slices. The cut surface reveals a tan-yellow, semi-porous parenchyma with a vaguely nodular appearance. There is no one discrete dominant mass or nodule. Representative sections are submitted as follows:

Cassette F1: Right apical margin, entirely submitted.
Cassette F2: Left apical margin, entirely submitted.

Right anterior quadrant

Cassette F3: Serial slice 2.
Cassette F4: Serial slice 4.
Cassette F5: Serial slice 7.

Right posterior quadrant

Cassette F6: Serial slice 2.
Cassette F7: Serial slice 4.
Cassette F8: Serial slice 5.
Cassette F9: Serial slice 8.

Left posterior quadrant

Cassette F10: Slice 3.
Cassette F11: Slice 5.
Cassette F12: Slice 6.
Cassette F13: Slice 8.

Left anterior quadrant

Cassette F14: Slice 2.
Cassette F15: Slice 5.
Cassette F16: Slice 7.
Cassette F17: Right bladder margin.
Cassette F18: Left bladder margin.
Cassette F19: Right seminal vesicle.
Cassette F20: Left seminal vesicle.

Part G is additionally labeled "left urethral margin." It consists of a single fragment of unoriented, tan-brown soft tissue measuring 1.4 x 0.6 x 0.3 cm in diameter. The specimen is entirely submitted in cassette G1.

Part H is additionally labeled "right urethral margin apex." It consists of a single fragment of unoriented, tan-brown soft tissue measuring 1.6 x 0.5 x 0.3 cm. The specimen is entirely submitted in cassette H1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed

Triplet Case

Triplet Case not Subm

Source: NCI Genomic Data Commons file b9b9fdc6-5b3c-4705-92b9-1f058ebc9755 (TCGA-V1-A9O5.4C94E826-144A-4879-99A3-E3B1655D4066.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).